TCGA case TCGA-2L-AAQE — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Technical University of Munich. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e7d5615-5142-4d53-a460-2cafade1f690

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Germany; Age at index: 56 years; Vital status: Dead; Days to death: 684 days (1.9 years); Cause of death: Cancer Related; Cause of death source: Death Certificate.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 56.4 years (20,618 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 684 days (1.9 years); Sites of involvement: Pancreas Head; Tumor grade category: Three Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 22; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 684 days (1.9 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Chronic Pancreatitis; Days to comorbidity: -171 days; Days to risk factor: -171 days; Risk factors: Chronic Pancreatitis.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Days to comorbidity: -171 days; Days to risk factor: -171 days; Risk factors: Diabetes, NOS.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 30.
- Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Alcohol drinks per day: 2; Alcohol days per week: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2L-AAQE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-2L-AAQE-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 20; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2L-AAQE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2L-AAQE-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 550 mg.
  Slide TCGA-2L-AAQE-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: With tumor; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 2; Alcohol exposure intensity: Daily Drinker; Alcohol consumption frequency: 7; Diabetes diagnosis indicator: Yes; History chronic pancreatitis: Yes; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Pancreatic Cancer.
- Follow-up form, New tumor event: New tumor event surgery: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 684 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 684 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 684 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2L-AAQE-01A-11D-A396-01): tumor purity 0.38, ploidy 3.42, whole-genome doublings 1.
